CCDI case PBCLUI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/4a4b5fd1-298e-4759-93be-fd1b23296b62

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 10.7 years (3,894 days).

Biospecimens (3 samples)
- Sample 0DUUP6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUUPP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUUQ3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
